Surgical pathology report (de-identified scan), TCGA case TCGA-DD-AAE4, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DD-AAE4-01A (Primary Tumor).

[page 1 of 2]
CLINICAL DIAGNOSIS: Hepatocellular carcinoma suggested

Specimen : Liver and Liver mass

Gross Photo :

GROSS:

Specimen status: Fresh

Operation: Partial hepatectomy

Organs: Liver (14.0 x 9.5 x 4.8 cm, 244.5 gm)

Lesion:

A well-defined red to pale tan round tumor mass (2.5 x 2.5 x 2.3 cm)

Cut surface: Red to pale tan firm and solid with area of hemorrhage

Gross type:

HCC: Expanding nodular, Multinodular confluent

Resection margin: Not involved grossly (safety margin: 0.5 cm)

Others:

Satellite nodule: No

Remaining parenchyma: Cirrhosis (stage 4)

Representative sections submitted

Gross photo: Present

Blocks

T1-3,TB, tumor mass x 4

L,NB, liver parenchyma x 2

ICD-O-3

Carcinoma, hepatocellular NOS
8170/3

Site: Liver C22.0

Q405/20/14

MICROSCOPIC:

Hepatocellular carcinoma: Yes

The worst differentiation I

The major differentiation I

Histologic type: Trabecular

Cell type: Hepatic

Fatty change: No

Fibrous capsule formation: No

Septum formation: No

Surgical resection margin invasion: No

Serosal invasion: No

Portal vein invasion: No

Microvessel invasion: No

Intrahepatic metastasis: No

Multicentric occurrence: No

SPECIAL STAIN:

Reticulum (partial loss), Trichrome (+, at peripheral cirrhotic liver)

NOT reported. Gross:

[page 2 of 2]
NOT reported. Gross:

cervix, smear, inflammation

Stomach, antrum, scopic, chronic gastritis, H. pylori, associated, erosion

Large intestine, sigmoid colon, scopic, tubular adenoma, low grade, dysplasia

Nasal cavity, nasal septum, biopsy, capillary hemangioma

Nasal cavity, biopsy, fungal ball, consistent with, aspergillus species

Nasal cavity, right, anterior nasal septum, excision, consistent with, lobular capillary hemangioma, erosion

Liver, ectomy, hepatocellular carcinoma, well differentiated, cirrhosis

T56000, P10, M81703, well differentiated, M49500

DIAGNOSIS:

Liver, partial hepatectomy:

Hepatocellular carcinoma, well differentiated

Cirrhosis

Suggestion :

Source: NCI Genomic Data Commons file f92fb801-8e19-4faa-8bdf-e76a82f7b5b2 (TCGA-DD-AAE4.2DDF43C9-8728-4CD6-977C-ECCE8B0BD322.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).